Somatic mutation profile of tumor specimen MMRF_2056_1_BM_CD138pos (aliquot MMRF_2056_1_BM_CD138pos_T1_KHS5U_L08060) from MMRF case MMRF_2056, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.7 years (18,506 days).
Specimen MMRF_2056_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b37f3dd2-3b5e-4c95-a277-17faea6feb56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2056_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2056_1_PB_Whole_C2_KHS5U_L08061; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/add7b705-0492-41a3-870f-ed85eeb67378

The open-access MAF lists 77 somatic variants for this specimen: 34 protein-altering or splice-affecting, 5 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, 3'UTR 24, Intron 8, Silent 5, 5'UTR 3, Nonsense Mutation 2, Splice Site 2, Translation Start Site 1, 3'Flank 1, Frame Shift Ins 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 74/151 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL6A3 | c.7814C>T p.S2605F | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.894); catalogued as COSV55109801; called by muse, mutect2, varscan2
- CRISPLD1 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs760405434; called by muse, mutect2
- EFNA3 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 116/300 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.314); catalogued as rs985996821; called by muse, mutect2
- EFNA3 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 117/296 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV100860861, COSV63625307; called by muse, mutect2
- GPR39 | c.151A>G p.T51A | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1009748267; called by muse, mutect2
- GTF2B | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as rs777916117; called by muse, mutect2, varscan2
- MAGED1 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 50/86 reads (58%) | catalogued as COSV58516107, COSV58516397; called by muse, mutect2, varscan2
- MDK | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs1212640061; called by muse, mutect2, varscan2
- OR51A7 | c.164T>G p.L55R | Missense Mutation (SNP) | VAF 79/150 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV63788438; called by muse, mutect2, varscan2
- RFTN1 | c.-8-1G>A | Splice Site (SNP) | VAF 131/428 reads (31%) | catalogued as rs1461345095; called by muse, mutect2, varscan2
- SERPINI2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 10/320 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV52988210; called by muse, mutect2
- SPTB | c.3745G>A p.V1249M | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.42); catalogued as rs1373154036; called by muse, mutect2, varscan2
- TCL1A | c.120G>A p.E40= | Splice Region (SNP) | VAF 83/190 reads (44%) | catalogued as rs767730962, COSV101268493; called by muse, varscan2
- ZAN | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1385432957, COSV61807898; called by muse, mutect2
- ABCA9 | c.3199T>A p.W1067R | Missense Mutation (SNP) | VAF 118/280 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFHR5 | c.82A>C p.I28L | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- CROT | c.1765dup p.A589Gfs*14 | Frame Shift Ins (INS) | VAF 143/492 reads (29%) | called by mutect2, pindel, varscan2
- CRYBB2 | c.236A>T p.Y79F | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- FGGY | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FLG2 | c.5545G>T p.G1849* | Nonsense Mutation (SNP) | VAF 122/255 reads (48%) | called by muse, mutect2, varscan2
- GMEB1 | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 164/381 reads (43%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- H1-5 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTR4 | c.101T>A p.L34H | Missense Mutation (SNP) | VAF 114/235 reads (49%) | PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- OTUD7A | c.1263C>A p.D421E (on ENST00000307050 / NM_001382637.1; = p.D414E on NM_130901.3) | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PDE2A | c.2510A>T p.E837V | Missense Mutation (SNP) | VAF 13/221 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- PRPF8 | c.2648G>A p.R883H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.978C>A p.F326L (on ENST00000352766; = p.F247L on NM_181334.5) | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RFX7 | c.4037C>T p.S1346L (on ENST00000559447 / NM_001368074.1; = p.S1443L on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- SAMHD1 | c.1491T>A p.D497E | Missense Mutation (SNP) | VAF 134/290 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- SCN3A | c.3437T>A p.V1146D | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2
- TCERG1L | c.1486-2A>G p.X496_splice | Splice Site (SNP) | VAF 36/69 reads (52%) | called by mutect2, varscan2
- TCHHL1 | c.797A>T p.K266I | Missense Mutation (SNP) | VAF 22/404 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2
- ZNF711 | c.272A>G p.E91G | Missense Mutation (SNP) | VAF 126/135 reads (93%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EP400 | c.3600C>T p.F1200= | Silent (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- IGKV2-24 | c.234C>T p.N78= | Silent (SNP) | VAF 90/258 reads (35%) | catalogued as rs376710864; called by muse, varscan2
- NYAP2 | c.597G>A p.P199= | Silent (SNP) | VAF 179/376 reads (48%) | catalogued as rs529456486, COSV56003344, COSV56006863, COSV56010363; called by muse, mutect2, varscan2
- PDE6A | c.2466G>T p.V822= | Silent (SNP) | VAF 94/210 reads (45%) | called by muse, mutect2, varscan2
- SPOCK3 | c.1179C>T p.G393= | Silent (SNP) | VAF 55/108 reads (51%) | catalogued as rs369877338; called by muse, mutect2, varscan2
- AC073310.1 | n.760A>T | RNA (SNP) | VAF 39/71 reads (55%) | called by muse, mutect2, varscan2
- ASAP2 | c.*1402T>C | 3'UTR (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- AVPR1A | c.*1995G>A | 3'UTR (SNP) | VAF 55/396 reads (14%) | catalogued as rs1404895075; called by muse, mutect2, varscan2
- C1QTNF9 | c.*223T>G | 3'UTR (SNP) | VAF 165/518 reads (32%) | called by muse, mutect2, varscan2
- CCDC198 | c.*421C>T | 3'UTR (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- CDH6 | c.*2496T>C | 3'UTR (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- COPS9 | c.63+88A>G | Intron (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- CRB1 | c.*337T>G | 3'UTR (SNP) | VAF 52/102 reads (51%) | called by muse, mutect2, varscan2
- DAOA | c.*111+48A>T | Intron (SNP) | VAF 76/175 reads (43%) | called by muse, mutect2, varscan2
- DCC | c.*1377C>T | 3'UTR (SNP) | VAF 51/87 reads (59%) | called by muse, mutect2, varscan2
- DOCK1 | c.*796G>A | 3'UTR (SNP) | VAF 44/97 reads (45%) | called by muse, mutect2, varscan2
- DST | c.4297-2780C>A | Intron (SNP) | VAF 157/356 reads (44%) | called by muse, mutect2, varscan2
- EFNA3 | c.*360G>C | 3'UTR (SNP) | VAF 72/158 reads (46%) | called by muse, mutect2, varscan2
- EFNA3 | c.*658G>T | 3'UTR (SNP) | VAF 96/255 reads (38%) | called by muse, mutect2, varscan2
- GTPBP10 | c.*1430C>G | 3'UTR (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- IQGAP1 | c.*1213A>T | 3'UTR (SNP) | VAF 28/81 reads (35%) | catalogued as rs909117690; called by muse, varscan2
- IRS2 | c.*853A>C | 3'UTR (SNP) | VAF 62/122 reads (51%) | called by muse, mutect2
- LRPAP1 | c.*5483G>A | 3'UTR (SNP) | VAF 36/88 reads (41%) | called by muse, mutect2
- MAP9 | c.*3802A>C | 3'UTR (SNP) | VAF 39/87 reads (45%) | called by muse, mutect2, varscan2
- MEF2C | chr5:88719054 A>G | 3'Flank (SNP) | VAF 44/88 reads (50%) | called by muse, mutect2, varscan2
- MSANTD2 | c.*399C>G | 3'UTR (SNP) | VAF 32/121 reads (26%) | catalogued as COSV99515972; called by muse, mutect2, varscan2
- MYO1E | c.-1C>T | 5'UTR (SNP) | VAF 25/45 reads (56%) | catalogued as rs554973305; called by muse, mutect2, varscan2
- MYO1E | c.-2C>T | 5'UTR (SNP) | VAF 26/48 reads (54%) | catalogued as rs573448797, COSV55686570; called by muse, mutect2, varscan2
- NOTO | c.*323A>G | 3'UTR (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- PKIA | c.*1101A>C | 3'UTR (SNP) | VAF 43/105 reads (41%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.*4274G>A | 3'UTR (SNP) | VAF 67/123 reads (54%) | catalogued as rs1054221904; called by muse, mutect2, varscan2
- PSG6 | chr19:42917882 C>T | 5'Flank (SNP) | VAF 91/214 reads (43%) | called by muse, varscan2
- RBM17 | c.*1597T>C | 3'UTR (SNP) | VAF 23/36 reads (64%) | called by muse, mutect2, varscan2
- SH3TC2 | c.3478+577G>C | Intron (SNP) | VAF 47/117 reads (40%) | catalogued as rs757075250; called by muse, mutect2, varscan2
- SLC12A5 | c.1405+36G>A | Intron (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- SLC25A44 | c.*1706G>A | 3'UTR (SNP) | VAF 85/231 reads (37%) | catalogued as rs192987568; called by muse, mutect2, varscan2
- SP100 | c.-164A>G | 5'UTR (SNP) | VAF 40/112 reads (36%) | catalogued as rs1045925115; called by muse, mutect2, varscan2
- ST13 | c.*1447T>C | 3'UTR (SNP) | VAF 161/329 reads (49%) | called by muse, mutect2, varscan2
- SULT1E1 | c.*64T>C | 3'UTR (SNP) | VAF 67/173 reads (39%) | called by muse, mutect2, varscan2
- TFAP2B | c.*167del | 3'UTR (DEL) | VAF 52/136 reads (38%) | catalogued as rs375026920; called by mutect2, varscan2
- TIAM1 | c.2217+120G>C | Intron (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- TNS3 | c.4194-165A>T | Intron (SNP) | VAF 82/159 reads (52%) | called by muse, mutect2, varscan2
- TSPEAR | c.1566+2355G>A | Intron (SNP) | VAF 16/241 reads (7%) | catalogued as rs1377346977; called by muse, mutect2
